Somatic mutation profile of tumor specimen TCGA-CJ-4904-01A (aliquot TCGA-CJ-4904-01A-02D-1429-08) from TCGA case TCGA-CJ-4904, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 60.3 years (22,036 days).
Specimen TCGA-CJ-4904-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fec8fe6-e1ac-4507-b0ff-d138b3955bc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4904-11A (Solid Tissue Normal), aliquot TCGA-CJ-4904-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/463d4753-ca42-4db2-9ab9-62c94463e22e

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 32, Silent 15, Frame Shift Del 4, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65928332; called by muse, mutect2
- AK8 | c.1157T>A p.M386K | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53762100; called by muse, mutect2, varscan2
- ATM | c.5033T>G p.V1678G | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV53780415; called by muse, varscan2
- BARD1 | c.312G>C p.M104I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.158); catalogued as rs752133770, COSV53618491, COSV99637815; called by muse, mutect2, varscan2
- CACNA1F | c.4559C>T p.T1520M | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs1192061637, COSV59905121; called by muse, mutect2
- CWC15 | c.187T>G p.L63V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54412684; called by muse, mutect2, varscan2
- DYM | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV53994672; called by muse, mutect2, varscan2
- ELFN2 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778343215, COSV68744414; called by muse, mutect2
- F5 | c.4021C>G p.P1341A | Missense Mutation (SNP) | VAF 71/340 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV63128760, COSV63129381; called by muse, mutect2, varscan2
- FSCB | c.2251G>C p.A751P | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100469684, COSV61219814; called by muse, mutect2
- GAB1 | c.194G>T p.C65F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53761646; called by muse, mutect2, varscan2
- GDF11 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV57690792; called by muse, mutect2, varscan2
- GPM6A | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1271491889, COSV54536347; called by muse, mutect2, varscan2
- GPR174 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV52132025; called by muse, mutect2
- GUCY2F | c.2955A>T p.S985= | Splice Region (SNP) | VAF 13/354 reads (4%) | catalogued as COSV54309620; called by muse, mutect2
- IGHA2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs782225895; called by muse, mutect2, varscan2
- ITGA11 | c.1059A>T p.E353D | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59882772; called by muse, mutect2, varscan2
- MOSPD3 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56157859, COSV56159077; called by muse, mutect2, varscan2
- NNT | c.687+1G>A p.X229_splice | Splice Site (SNP) | VAF 32/82 reads (39%) | catalogued as COSV52930476; called by muse, varscan2
- OR2B3 | c.83T>C p.F28S | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1394044458, COSV65851245; called by muse, mutect2, varscan2
- PAN3 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56708066; called by muse, mutect2
- PISD | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV60674972; called by muse, mutect2, varscan2
- PLEKHO2 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as COSV60263239; called by muse, mutect2, varscan2
- PPP1R14B | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV58588711; called by muse, mutect2, varscan2
- RAI1 | c.3574A>G p.S1192G | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55400282; called by muse, mutect2, varscan2
- RRAGC | c.689G>T p.S230I | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65932154; called by muse, mutect2
- SGCZ | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV66049863; called by muse, mutect2
- TFAP2C | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52373670; called by muse, mutect2
- TGM5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55012768; called by muse, mutect2, varscan2
- TRIM28 | c.461C>G p.T154S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.924); catalogued as COSV53402044; called by muse, mutect2, varscan2
- TRMT13 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64502554; called by muse, mutect2, varscan2
- VAC14 | c.473A>G p.D158G | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55758666; called by muse, mutect2
- WAC | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV61570185; called by muse, mutect2
- ZBTB40 | c.440A>C p.E147A | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.914); catalogued as COSV65146628; called by muse, mutect2, varscan2
- ZNF236 | c.2848del p.A950Hfs*33 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | catalogued as COSV53499080; called by mutect2, pindel, varscan2
- ZNF407 | c.2056C>A p.P686T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV55274099; called by muse, mutect2, varscan2
- ADH4 | c.1092del p.F365Lfs*3 | Frame Shift Del (DEL) | VAF 38/224 reads (17%) | called by mutect2, pindel, varscan2
- CYP1B1 | c.758del p.P253Rfs*25 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel, varscan2
- KDM7A | c.1894del p.E632Kfs*7 | Frame Shift Del (DEL) | VAF 30/181 reads (17%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2973dup p.W992Mfs*12 | Frame Shift Ins (INS) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- TADA2A | c.1191C>A p.Y397* | Nonsense Mutation (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- VHL | c.556dup p.E186Gfs*70 | Frame Shift Ins (INS) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.1497G>A p.K499= | Silent (SNP) | VAF 18/317 reads (6%) | catalogued as rs372413157; called by muse, mutect2
- ARHGEF7 | c.408G>A p.G136= (on ENST00000375741 / NM_001113511.2; = p.G115= on NM_145735.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/522 reads (7%) | catalogued as COSV54553371; called by muse, mutect2
- DSCAM | c.5572C>T p.L1858= | Silent (SNP) | VAF 18/215 reads (8%) | catalogued as COSV68038269; called by muse, mutect2
- ERCC8 | c.1125C>T p.C375= (on ENST00000265038; = p.C356= on NM_000082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as rs141898557, COSV54018958; called by muse, mutect2
- FOXQ1 | c.418T>C p.L140= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57259570; called by mutect2, varscan2
- ICE2 | c.2088A>G p.G696= | Silent (SNP) | VAF 7/124 reads (6%) | catalogued as COSV55034486; called by muse, mutect2
- KRT73 | c.108C>A p.G36= | Silent (SNP) | VAF 20/147 reads (14%) | catalogued as COSV59841988; called by muse, mutect2, varscan2
- N4BP2L2 | c.282T>C p.I94= | Silent (SNP) | VAF 18/456 reads (4%) | catalogued as rs1418344730, COSV57230557; called by muse, mutect2
- NBPF3 | c.282C>G p.L94= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as COSV59058316; called by muse, mutect2, varscan2
- NLRP8 | c.48C>T p.S16= | Silent (SNP) | VAF 17/242 reads (7%) | catalogued as COSV52595187; called by muse, mutect2
- PTCD3 | c.1356A>G p.Q452= | Silent (SNP) | VAF 62/249 reads (25%) | catalogued as rs375762783; called by muse, mutect2, varscan2
- SNCA | c.276T>C p.T92= | Silent (SNP) | VAF 45/182 reads (25%) | catalogued as COSV61131717, COSV61137549; called by muse, mutect2, varscan2
- TARBP1 | c.2898C>T p.C966= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV50212870; called by muse, mutect2
- ZNF112 | c.642T>C p.S214= (on ENST00000337401 / NM_001083335.2; = p.S208= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/243 reads (7%) | catalogued as rs1406666888, COSV61622395; called by muse, mutect2
- ZNF124 | c.717T>C p.C239= (on ENST00000543802 / NM_001297568.1; = p.C177= on NM_003431.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/188 reads (6%) | catalogued as COSV100517754; called by muse, mutect2
